Somatic mutation profile of tumor specimen TARGET-30-PALZZV-01A (aliquot TARGET-30-PALZZV-01A-01W) from TARGET case TARGET-30-PALZZV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.9 years (699 days).
Specimen TARGET-30-PALZZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 292c075b-4a53-4da0-95f1-923ec454b66e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALZZV-10A (Blood Derived Normal), aliquot TARGET-30-PALZZV-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8819c1ae-b817-4a3c-806c-a57c9289ee3a

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY10 | c.750G>T p.R250S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV63245646; called by muse, mutect2
- APEH | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV56529535; called by muse, mutect2
- CHRNA4 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs745790876, COSV64721393; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUSP9 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61438574; called by muse, mutect2, varscan2
- HMCN1 | c.7870A>G p.I2624V | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.941); catalogued as COSV54947594; called by muse, mutect2, varscan2
- LILRB1 | c.277G>T p.E93* (on ENST00000427581; = p.E57* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 60/150 reads (40%) | catalogued as COSV100206772, COSV61115924; called by muse, varscan2
- MAN2B1 | c.2398G>T p.G800W | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123456, CM124095, CM124096, COSV55475752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP7D2 | c.987G>T p.M329I | Missense Mutation (SNP) | VAF 188/302 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65530927; called by muse, mutect2, varscan2
- MERTK | c.2862C>A p.N954K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54936847; called by muse, mutect2, varscan2
- RYR1 | c.3695C>A p.P1232Q | Missense Mutation (SNP) | VAF 152/361 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.601); catalogued as COSV62113183; called by muse, mutect2, varscan2
- SLC25A31 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55420485; called by muse, mutect2, varscan2
- TBC1D1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs761530736, COSV54728513; called by muse, mutect2, varscan2
- ZFP14 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749848475, COSV54205439; called by muse, mutect2, varscan2
- RAG2 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- TINAG | c.1120_1124del p.V374Sfs*7 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | called by mutect2, pindel, varscan2
- MESD | c.429C>T p.A143= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV55726659; called by muse, mutect2, varscan2
- ZNF761 | c.1080C>A p.G360= | Silent (SNP) | VAF 146/352 reads (41%) | catalogued as COSV61889626; called by muse, mutect2, varscan2
